Gene-level copy-number profile of tumor specimen TCGA-05-4395-01A from TCGA case TCGA-05-4395, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 76.6 years (27,971 days).
Specimen TCGA-05-4395-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.6b772529-8e35-4607-8add-6b15914b3ab5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-05-4395-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ce4eb0c4-9626-4117-a93b-7f3c8fc1daf1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,432; copy number 2: 17,805; copy number 3: 19,376; copy number 4: 12,619; copy number 5: 6,155; copy number 6: 274; copy number 7: 61; copy number 9: 732; copy number 10: 76; copy number 11: 21; copy number 12: 62; copy number 16: 68; copy number 17: 129.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-05-4395-01A-01D-1204-01): tumor purity 0.61, ploidy 3.22, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,149 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:95,297,676–103,989,658, 280 genes, copy number 11–17 (broad region; genes not listed).
- chr12:66,767–34,249,958, 849 genes, copy number 7–10 (broad region; genes not listed).
- chr15:61,852,389–62,060,473, 1 gene, copy number 7 (within-gene range 2–7): VPS13C.
- chr15:62,060,503–62,844,631, 19 genes, copy number 7 (within-gene range 2–7): AC104590.1, C2CD4A, NPM1P47, C2CD4B, AC126323.2, AC126323.1, AC126323.3, Metazoa_SRP, GOLGA2P11, AC126323.4, AC126323.6, AC126323.5, MIR8067, MIR6085, HMGN1P26, AC032011.1, TLN2, MGC15885, AC100839.1.

Autosomal genes at a single copy (total copy number 1): 53. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
